Somatic mutation profile of tumor specimen C3N-02811-02 (aliquot CPT0158390009) from CPTAC case C3N-02811, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 74.7 years (27,281 days).
Specimen C3N-02811-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a18ca3b8-2900-47f2-941e-0e12174b7546.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02811-31 (Blood Derived Normal), aliquot CPT0159420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/995feaa1-beef-4561-bf40-5483c51eff69

The open-access MAF lists 74 somatic variants for this specimen: 44 protein-altering or splice-affecting, 16 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 16, Intron 9, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 2, 5'UTR 2, 3'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.266T>A p.L89H | Missense Mutation (SNP) | VAF 167/618 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs5030807, CM941368, COSV56543066, COSV56543312, COSV56543561; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs765118960; called by muse, mutect2, varscan2
- CELSR2 | c.7563G>C p.W2521C | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54768989; called by muse, mutect2
- COL6A5 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.765); catalogued as rs548996198; called by muse, mutect2, varscan2
- EYS | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as rs901144230, COSV58196837; called by muse, mutect2
- FHAD1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 17/517 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1206989930; called by muse, mutect2
- KCNN2 | c.1040G>T p.G347V (on ENST00000264773; = p.G559V on NM_021614.4) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs770666617; called by muse, mutect2
- MPP4 | c.44A>C p.D15A | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as COSV100207156; called by muse, mutect2, varscan2
- NEDD1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99901198; called by mutect2, varscan2
- PRG4 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.493); catalogued as COSV66622868; called by muse, mutect2, varscan2
- PSG6 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.116); catalogued as rs1568448003; called by muse, mutect2, varscan2
- SDHAF2 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 107/615 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV100074040; called by muse, mutect2, varscan2
- TCP10L2 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs761436101, COSV52083706; called by muse, mutect2, varscan2
- ZNF541 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 20/704 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1347792087, COSV54545132; called by muse, mutect2
- ANAPC1 | c.3822_3823dup p.A1275Gfs*4 | Frame Shift Ins (INS) | VAF 24/142 reads (17%) | called by mutect2, varscan2
- BCAS3 | c.2518C>T p.P840S (on ENST00000390652 / NM_001353144.2; = p.P825S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- CARMIL3 | c.2297del p.E766Gfs*4 | Frame Shift Del (DEL) | VAF 28/125 reads (22%) | called by mutect2, pindel, varscan2
- CD8A | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 109/634 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRACD | c.3400G>A p.G1134R | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- DCP2 | c.1185C>A p.C395* | Nonsense Mutation (SNP) | VAF 40/324 reads (12%) | called by muse, mutect2, varscan2
- DPY30 | c.53_56del p.H18Lfs*12 | Frame Shift Del (DEL) | VAF 45/322 reads (14%) | called by mutect2, pindel, varscan2
- ENAH | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAT1 | c.8888C>G p.P2963R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- IDUA | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MEIS2 | c.280G>T p.E94* (on ENST00000561208 / NM_170675.5; = p.E81* on NM_002399.3) | Nonsense Mutation (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- MORC1 | c.343A>C p.I115L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MRPS30 | c.599T>A p.L200H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, varscan2
- NTF3 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 32/487 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- ORC3 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PKHD1 | c.3815G>A p.W1272* | Nonsense Mutation (SNP) | VAF 88/390 reads (23%) | called by mutect2, varscan2
- RHOBTB2 | c.946C>G p.P316A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCARF1 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); called by muse, mutect2
- SCUBE3 | c.2472_2475del p.Y824* | Frame Shift Del (DEL) | VAF 69/467 reads (15%) | called by mutect2, pindel, varscan2
- SLC47A2 | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 80/465 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTB | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ST14 | c.1433C>G p.T478S | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- STXBP5 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SYNE1 | c.18503del p.K6168Sfs*2 (on ENST00000367255 / NM_182961.4; = p.K6097Sfs*2 on NM_033071.3) | Frame Shift Del (DEL) | VAF 67/351 reads (19%) | called by mutect2, pindel, varscan2
- TBC1D32 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TFAP2A | c.428G>A p.S143N (on ENST00000482890; = p.S135N on NM_001032280.3) | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2
- TRIM71 | c.2097G>C p.Q699H | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VCAN | c.6330dup p.E2111* | Frame Shift Ins (INS) | VAF 53/380 reads (14%) | called by mutect2, pindel, varscan2
- WDR35 | c.2428T>C p.F810L (on ENST00000345530 / NM_001006657.2; = p.F799L on NM_020779.4) | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF98 | c.1270C>G p.H424D | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF3 | c.3246G>C p.L1082= | Silent (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- C7orf33 | c.*1_*3del | Silent (DEL) | VAF 38/167 reads (23%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.2520T>C p.S840= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs1439229320; called by muse, mutect2, varscan2
- DRC7 | c.135G>A p.K45= | Silent (SNP) | VAF 78/409 reads (19%) | called by muse, mutect2, varscan2
- GALNT6 | c.933C>G p.P311= | Silent (SNP) | VAF 139/620 reads (22%) | catalogued as COSV62542202, COSV62542435; called by muse, mutect2, varscan2
- GLUD2 | c.1149C>T p.A383= | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- GPR45 | c.672G>A p.K224= | Silent (SNP) | VAF 63/301 reads (21%) | called by muse, mutect2, varscan2
- KRT33A | c.243C>T p.N81= | Silent (SNP) | VAF 28/730 reads (4%) | catalogued as rs779772146; called by muse, mutect2
- NCOA2 | c.3501A>G p.T1167= | Silent (SNP) | VAF 142/659 reads (22%) | called by muse, mutect2, varscan2
- NET1 | c.642A>G p.E214= (on ENST00000355029 / NM_001047160.3; = p.E160= on NM_005863.5) | Silent (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- NOMO1 | c.3573A>G p.L1191= | Silent (SNP) | VAF 171/1724 reads (10%) | catalogued as COSV55058162; called by muse, mutect2
- SDSL | c.858C>A p.G286= | Silent (SNP) | VAF 15/236 reads (6%) | called by muse, mutect2
- SH2B1 | c.2196G>A p.Q732= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- SP4 | c.1404T>C p.S468= | Silent (SNP) | VAF 87/393 reads (22%) | catalogued as rs1212762331; called by muse, mutect2, varscan2
- TMEM131 | c.3486C>G p.P1162= | Silent (SNP) | VAF 68/359 reads (19%) | called by muse, mutect2, varscan2
- ZNF461 | c.63A>G p.E21= | Silent (SNP) | VAF 15/386 reads (4%) | called by muse, mutect2
- AC010507.1 | chr19:200365 G>C | 3'Flank (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2
- AIFM1 | c.249+1255G>T | Intron (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- G3BP2 | c.442+29dup | Intron (INS) | VAF 29/155 reads (19%) | called by mutect2, pindel, varscan2
- GH1 | c.-49C>T | 5'UTR (SNP) | VAF 89/424 reads (21%) | catalogued as rs997930910; called by muse, mutect2, varscan2
- KIAA1328 | c.1232+16659G>T | Intron (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54449938; called by muse, mutect2, varscan2
- PPP1R8 | c.*1202A>C | 3'UTR (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- PRPF3 | c.1844-25G>T | Intron (SNP) | VAF 38/194 reads (20%) | called by muse, mutect2, varscan2
- SLC22A8 | c.885+66C>G | Intron (SNP) | VAF 35/161 reads (22%) | called by muse, mutect2, varscan2
- TEX29 | c.170-522C>G | Intron (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- TOR1A | c.444+102C>T | Intron (SNP) | VAF 53/202 reads (26%) | catalogued as rs770323357; called by muse, mutect2, varscan2
- TSPAN10 | c.788+23G>A | Intron (SNP) | VAF 227/960 reads (24%) | called by muse, mutect2, varscan2
- UEVLD | c.-23C>A | 5'UTR (SNP) | VAF 44/191 reads (23%) | catalogued as rs373177272; called by muse, mutect2, varscan2
- Y_RNA | chr1:31507463 C>T | 5'Flank (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- ZNF8 | c.66+15A>C | Intron (SNP) | VAF 51/174 reads (29%) | called by muse, mutect2, varscan2
